Somatic mutation profile of tumor specimen TCGA-BR-4201-01A (aliquot TCGA-BR-4201-01A-01D-1126-08) from TCGA case TCGA-BR-4201, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G1; Age at diagnosis: 66.7 years (24,354 days).
Specimen TCGA-BR-4201-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 835ee333-b2e1-4704-8b11-0b4955a8a5b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4201-11A (Solid Tissue Normal), aliquot TCGA-BR-4201-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d015d5b5-8a0a-4a65-8290-1264225dca21

The open-access MAF lists 1,701 somatic variants for this specimen: 1,314 protein-altering or splice-affecting, 351 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 785, Frame Shift Del 379, Silent 351, Frame Shift Ins 65, Nonsense Mutation 48, In Frame Del 14, Intron 13, Splice Site 12, RNA 10, Splice Region 9, 3'UTR 7, 5'Flank 3.

Variants (750 of 1,701; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- F8 | c.4379del p.N1460Ifs*5 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs387906455, CD910498; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.584+2T>C p.X195_splice (on ENST00000281708 / NM_001349798.2; = p.X115_splice on NM_018315.5) | Splice Site (SNP) | VAF 4/15 reads (27%) | hotspot (GDC flag); catalogued as COSV55932079, COSV55965874; called by muse, mutect2
- GNPTAB | c.2693del p.K898Sfs*13 | Frame Shift Del (DEL) | VAF 24/160 reads (15%) | catalogued as rs281864999, CD090839; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MECP2 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as rs61750240, CD002178, CM000749, COSV57657683; ClinVar: pathogenic; called by muse, varscan2
- MOCS2 | c.65del p.P22Hfs*2 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | catalogued as rs398122799; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NIPBL | c.5455C>T p.R1819* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs587783975, CM071043, COSV56968340; ClinVar: pathogenic; called by mutect2, varscan2
- NPHP1 | c.555del p.K185Nfs*7 | Frame Shift Del (DEL) | VAF 16/105 reads (15%) | catalogued as rs766524637, CD1511891; ClinVar: pathogenic; called by mutect2, varscan2
- NSD1 | c.7180A>G p.I2394V | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1554207690, COSV61786154; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PKD2 | c.2159del p.N720Ifs*17 | Frame Shift Del (DEL) | VAF 21/148 reads (14%) | catalogued as rs757757289; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SACS | c.8888del p.F2963Sfs*15 | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | catalogued as rs1555250872; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SACS | c.8612dup p.L2871Ffs*29 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | catalogued as rs1057517212; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TALDO1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs151052416, CM051653; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AAAS | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52934624; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 34/165 reads (21%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCA1 | c.391A>T p.T131S | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV66059092, COSV66060190; called by muse, mutect2, varscan2
- ABCA12 | c.2141G>A p.R714Q (on ENST00000272895 / NM_173076.3; = p.R396Q on NM_015657.3) | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs558822558, COSV55954651; called by muse, mutect2, varscan2
- ABCA9 | c.4160C>T p.A1387V | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV60631059, COSV60631958; called by muse, mutect2, varscan2
- ABCA9 | c.2465T>C p.L822P | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1294052689, COSV60631971; called by muse, mutect2, varscan2
- ABCB1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs201280497, COSV55965306; called by muse, mutect2, varscan2
- ABCB6 | c.2386G>A p.V796I | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753788507, COSV54694689; called by muse, mutect2, varscan2
- ABCC8 | c.652C>A p.L218M | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.923); catalogued as COSV56858771; called by muse, mutect2
- ABCC9 | c.2756A>G p.Q919R | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV53988511; called by muse, mutect2, varscan2
- ABHD14A | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs758679870, COSV56473731; called by muse, mutect2, varscan2
- ABHD2 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61776627; called by muse, mutect2, varscan2
- ACAD10 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.254); catalogued as COSV58164230; called by muse, mutect2, varscan2
- ACD | c.1464G>T p.W488C (on ENST00000620338; = p.W399C on NM_022914.3) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV54670854; called by muse, mutect2, varscan2
- ACE2 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV53028136; called by muse, mutect2, varscan2
- ACO1 | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs757678488, COSV59385650; called by muse, mutect2, varscan2
- ACRBP | c.1077G>A p.S359= | Splice Region (SNP) | VAF 8/54 reads (15%) | catalogued as rs767126238, COSV57525665; called by mutect2, varscan2
- ACSBG2 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53128244; called by muse, mutect2, varscan2
- ACTL6B | c.392A>T p.E131V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV50519878; called by muse, mutect2, varscan2
- ACTN2 | c.2194G>A p.A732T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.989); catalogued as rs777744290, COSV63978407; ClinVar: uncertain significance; called by mutect2, varscan2
- ADAM18 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); catalogued as COSV55856509; called by muse, mutect2, varscan2
- ADAM30 | c.1865del p.N622Ifs*71 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | catalogued as rs750058585; called by mutect2, varscan2
- ADAMTS1 | c.1619G>A p.C540Y | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53173986; called by muse, mutect2
- ADAMTS12 | c.3899T>C p.L1300P | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.942); catalogued as rs201770938, COSV61272956, COSV61282807; called by muse, mutect2, varscan2
- ADAMTS13 | c.3250T>G p.C1084G | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52472032, COSV99390273; called by muse, mutect2, varscan2
- ADAMTS17 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.493); catalogued as rs372097810; called by muse, mutect2, varscan2
- ADAMTS18 | c.2077T>A p.F693I | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51398271, COSV51424094; called by muse, mutect2, varscan2
- ADAMTS19 | c.1973G>A p.G658E | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50807614; called by muse, mutect2
- ADAMTS2 | c.669del p.P224Hfs*23 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs748037345; called by mutect2, pindel, varscan2
- ADAMTS20 | c.2077A>C p.M693L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV67140896; called by muse, mutect2, varscan2
- ADAMTS6 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV66865435; called by muse, mutect2, varscan2
- ADAMTS9 | c.4549G>A p.V1517I | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.021); catalogued as rs868532784, COSV55792269; called by muse, mutect2, varscan2
- ADAMTSL2 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); catalogued as rs139661631, COSV63204569; called by mutect2, varscan2
- ADAP1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs761457256, COSV56218112; called by muse, mutect2, varscan2
- ADCY9 | c.2885C>T p.P962L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs768405098, COSV53576198; called by mutect2, varscan2
- ADD1 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs775330429, COSV53275200; called by mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 22/127 reads (17%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB3 | c.3125T>G p.L1042W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53262792; called by muse, mutect2, varscan2
- ADH1A | c.344del p.N115Tfs*3 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | catalogued as rs1560518334; called by mutect2, pindel, varscan2
- ADHFE1 | c.1108A>G p.T370A | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV52559633; called by muse, mutect2
- ADPRS | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1293906648, COSV52882351; called by muse, mutect2, varscan2
- AFDN | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs756328633, COSV60047255; called by muse, mutect2, varscan2
- AGFG2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as rs756748781, COSV53544174, COSV53547489; called by muse, mutect2, varscan2
- AGO2 | c.1010C>G p.T337S | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV55053533; called by muse, mutect2, varscan2
- AHCTF1 | c.1254T>A p.F418L (on ENST00000366508; = p.F392L on NM_015446.5) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV58256723; called by muse, mutect2, varscan2
- AHCYL2 | c.372G>C p.Q124H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as COSV61491765; called by muse, mutect2, varscan2
- AHNAK | c.9438G>A p.W3146* | Nonsense Mutation (SNP) | VAF 56/339 reads (17%) | catalogued as COSV57233934; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs778351035; called by mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKIRIN2 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as rs944028378, COSV57637866; called by muse, mutect2, varscan2
- AKR1B1 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53649169; called by muse, mutect2, varscan2
- ALDH3A2 | c.1201G>T p.G401* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as COSV51569158; called by muse, mutect2, varscan2
- ALG10 | c.653A>T p.D218V | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV56794451; called by muse, mutect2
- ALMS1 | c.938del p.L313Yfs*18 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs771675011; called by mutect2, pindel, varscan2
- ALMS1 | c.8162G>A p.R2721Q | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.181); catalogued as rs745857579, COSV52507270; called by muse, mutect2, varscan2
- ALOXE3 | c.2105C>A p.P702H | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59078365; called by muse, mutect2, varscan2
- ALPI | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs758457956, COSV55016146; called by mutect2, varscan2
- ALPK1 | c.3063del p.K1021Nfs*18 | Frame Shift Del (DEL) | VAF 40/237 reads (17%) | catalogued as rs1159828137; called by mutect2, pindel, varscan2
- AMOT | c.1926G>T p.Q642H (on ENST00000371959 / NM_001113490.1; = p.Q233H on NM_133265.3) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM166327, COSV59062321; called by muse, mutect2, varscan2
- AMOTL2 | c.599del p.P200Lfs*19 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs756346527; called by mutect2, pindel, varscan2
- AMPD1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62419485; called by muse, mutect2, varscan2
- ANAPC15 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); catalogued as COSV56194000; called by muse, mutect2, varscan2
- ANK3 | c.4817C>T p.T1606M | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1415082553, COSV55085768; called by muse, mutect2, varscan2
- ANKMY1 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs181851692, COSV56042117; called by mutect2, varscan2
- ANKRD26 | c.94del p.E32Rfs*42 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs1394661639; called by pindel, varscan2
- ANO6 | c.1906T>C p.F636L | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1286814659, COSV57669130; called by muse, mutect2, varscan2
- ANO7 | c.2771C>T p.T924M (on ENST00000274979; = p.T870M on NM_001370694.2) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs370010636; called by mutect2, varscan2
- ANO9 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758562981, COSV60385574; called by muse, mutect2, varscan2
- ANXA9 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as rs747931802, COSV64485694; called by muse, mutect2, varscan2
- AP2A2 | c.170del p.K57Sfs*24 | Frame Shift Del (DEL) | VAF 28/128 reads (22%) | catalogued as rs753029866; called by mutect2, varscan2
- AP3D1 | c.3410C>T p.T1137M | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs200727342; called by muse, mutect2, varscan2
- AP3D1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225987510, COSV61429432; called by muse, mutect2, varscan2
- APBB2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55964419; called by muse, mutect2, varscan2
- APLP2 | c.847T>C p.Y283H | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.629); catalogued as COSV53845184; called by muse, mutect2, varscan2
- APOBEC4 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.554); catalogued as rs776471890, COSV58017479; called by muse, mutect2, varscan2
- ARFGEF3 | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs767837982, COSV52472669; called by mutect2, varscan2
- ARHGAP17 | c.1792G>A p.A598T (on ENST00000289968 / NM_001006634.3; = p.A520T on NM_018054.6) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as COSV51512880; called by muse, varscan2
- ARHGAP24 | c.893G>A p.R298H (on ENST00000395184 / NM_001025616.3; = p.R205H on NM_031305.3) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1007199761, COSV51988098; called by muse, mutect2, varscan2
- ARHGAP25 | c.419A>G p.E140G (on ENST00000409202 / NM_001007231.3; = p.E133G on NM_014882.3) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54910203; called by muse, mutect2, varscan2
- ARHGAP29 | c.3776A>G p.Q1259R | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.477); catalogued as COSV53117826; called by muse, mutect2, varscan2
- ARHGAP39 | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV52776462; called by muse, mutect2, varscan2
- ARHGEF11 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63815991; called by muse, mutect2, varscan2
- ARID1A | c.3142C>T p.P1048S | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61390508; called by muse, mutect2, varscan2
- ARID1B | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.742); catalogued as rs563771544, COSV51673928; called by mutect2, varscan2
- ARMC2 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753812764, COSV64553660; called by mutect2, varscan2
- ARNT2 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs147344883, COSV57585373; called by mutect2, varscan2
- ART5 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs1247136254, COSV63365498; called by muse, mutect2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASB5 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs1401037963, COSV56671192; called by muse, mutect2, varscan2
- ASB7 | c.670A>G p.R224G | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as COSV58404726; called by muse, mutect2, varscan2
- ASCC1 | c.799G>A p.A267T (on ENST00000342444 / NM_001369085.1; = p.A239T on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760239155, COSV57729444; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as rs747570359; called by mutect2, varscan2
- ASPM | c.2760+2T>C p.X920_splice | Splice Site (SNP) | VAF 12/79 reads (15%) | catalogued as COSV54140268; called by muse, mutect2, varscan2
- ASXL3 | c.3682C>T p.P1228S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.012); catalogued as rs749701695, COSV52481956; called by mutect2, varscan2
- ASXL3 | c.5189T>A p.V1730D | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs1468601856, COSV52481975; called by muse, mutect2, varscan2
- ATF7IP | c.3647T>C p.I1216T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs773892983, COSV53779074; called by muse, mutect2, varscan2
- ATG14 | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 25/127 reads (20%) | catalogued as COSV55958522; called by muse, mutect2, varscan2
- ATP13A2 | c.3037A>G p.T1013A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV58704414; called by muse, mutect2, varscan2
- ATPSCKMT | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs559270054, COSV54726807, COSV99725982; called by muse, mutect2, varscan2
- ATR | c.7640G>A p.R2547Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.678); catalogued as COSV63390096; called by muse, mutect2, varscan2
- ATR | c.5588G>A p.S1863N | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.499); catalogued as COSV63394753; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- AVEN | c.717dup p.P240Afs*4 | Frame Shift Ins (INS) | VAF 9/52 reads (17%) | catalogued as rs759306134; called by mutect2, pindel, varscan2
- B4GALT4 | c.917A>G p.H306R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV63296528; called by muse, mutect2, varscan2
- BACH2 | c.865A>G p.I289V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV57611159; called by muse, mutect2, varscan2
- BAP1 | c.1810G>A p.V604M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs369065146, CM1515146; ClinVar: uncertain significance; called by mutect2, varscan2
- BBS9 | c.2068G>A p.A690T (on ENST00000242067 / NM_001348036.1; = p.A650T on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV54190476; called by muse, mutect2, varscan2
- BCL9 | c.3524G>A p.G1175D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV52351132; called by muse, mutect2, varscan2
- BDP1 | c.6647C>T p.T2216I | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV62435502; called by muse, mutect2, varscan2
- BHMT2 | c.755T>C p.F252S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54874979; called by muse, mutect2, varscan2
- BMI1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.025); catalogued as COSV64959754; called by muse, mutect2, varscan2
- BMX | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV59594057; called by muse, mutect2, varscan2
- BOC | c.2425A>G p.T809A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV56358906; called by muse, mutect2, varscan2
- BOD1L1 | c.8087G>A p.G2696E | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV50006881, COSV50088138; called by muse, mutect2, varscan2
- BRAF | c.1927C>T p.R643* (on ENST00000288602 / NM_001374244.1; = p.R603* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | catalogued as rs104886015, COSV56183050, COSV56377255; ClinVar: not provided; called by muse, mutect2, varscan2
- BRD1 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53454418; called by muse, mutect2, varscan2
- BRINP3 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV66543431; called by muse, varscan2
- BRINP3 | c.1015T>C p.S339P | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs746379368, COSV66543434; called by muse, varscan2
- BRPF1 | c.2204A>G p.Q735R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1471386300, COSV57408528; called by muse, mutect2, varscan2
- BRSK2 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1289959412, COSV57550038; called by muse, mutect2
- BUB1 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.351); catalogued as COSV57067671; called by muse, mutect2, varscan2
- C12orf45 | c.551del p.K184Rfs*13 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs777032057; called by mutect2, varscan2
- C16orf90 | c.397C>T p.R133* (on ENST00000399645 / NM_001353385.2; = p.R124* on NM_001080524.2) | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as rs753347972, COSV68714701; called by muse, mutect2, varscan2
- C1orf216 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779116618, COSV52046561; called by muse, mutect2, varscan2
- C1orf87 | c.904A>G p.R302G | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV64599242; called by muse, mutect2, varscan2
- C2orf68 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs760612952, COSV60473390; called by muse, mutect2, varscan2
- C6orf136 | c.238A>G p.S80G | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV53316234; called by muse, mutect2, varscan2
- CACNA1C | c.1057A>G p.M353V | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV59780456; called by muse, mutect2, varscan2
- CACNA1E | c.3526G>A p.V1176I | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.48); catalogued as rs1228218600, COSV62382262; called by muse, mutect2, varscan2
- CACNA1E | c.4639T>C p.F1547L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV62381306, COSV62433759; called by muse, mutect2, varscan2
- CACNA1H | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62006056; called by muse, mutect2, varscan2
- CACNA1S | c.3625A>C p.S1209R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV62944577; called by muse, mutect2, varscan2
- CAMSAP1 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1265391740, COSV56719110; called by mutect2, varscan2
- CAPN2 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs760400151, COSV54340559; called by mutect2, varscan2
- CARD14 | c.2086C>T p.Q696* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV60126229; called by muse, mutect2, varscan2
- CARMIL1 | c.3202A>G p.S1068G | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1367404162, COSV61524902; called by muse, mutect2, varscan2
- CASD1 | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51976019; called by muse, mutect2, varscan2
- CASP8AP2 | c.5726C>T p.T1909I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as COSV99386903; called by mutect2, varscan2
- CCAR2 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as COSV51515309; called by muse, mutect2, varscan2
- CCDC105 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757213881, COSV52965891; called by muse, mutect2, varscan2
- CCDC146 | c.1101G>T p.M367I | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV53555583; called by muse, mutect2, varscan2
- CCDC27 | c.1915dup p.L639Pfs*? | Frame Shift Ins (INS) | VAF 17/76 reads (22%) | catalogued as rs751021664; called by mutect2, varscan2
- CCDC62 | c.2036del p.N679Ifs*18 | Frame Shift Del (DEL) | VAF 16/105 reads (15%) | catalogued as rs1053262354; called by mutect2, pindel, varscan2
- CCDC81 | c.1297C>A p.L433M (on ENST00000445632 / NM_001156474.2; = p.L343M on NM_021827.4) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV53582168; called by muse, mutect2, varscan2
- CCDC83 | c.752A>T p.D251V | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.626); catalogued as COSV54705375; called by muse, mutect2
- CCDC88A | c.3603-3del | Splice Region (DEL) | VAF 8/84 reads (10%) | catalogued as rs768846308; called by pindel, varscan2
- CCKBR | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs775117809, COSV58106510; called by mutect2, varscan2
- CCN6 | c.624del p.K208Nfs*24 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | catalogued as rs781790231; called by mutect2, varscan2
- CCNC | c.447C>A p.C149* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100412571; called by muse, mutect2, varscan2
- CCNE2 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57377714; called by muse, mutect2
- CCT2 | c.113T>C p.L38S | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54741876; called by muse, mutect2
- CCT4 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV66702210; called by muse, mutect2, varscan2
- CCZ1B | c.1370del p.N457Mfs*4 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs777044936; called by mutect2, varscan2
- CD3E | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62346786; called by muse, mutect2, varscan2
- CD44 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs767614676, COSV53531780; called by muse, mutect2, varscan2
- CDC42EP4 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV59963999, COSV59964441; called by muse, mutect2, varscan2
- CDC5L | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.08); catalogued as rs748222402, COSV65177474; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH11 | c.1795G>A p.G599R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV51764630; called by muse, mutect2, varscan2
- CDH16 | c.1042C>T p.L348F | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs79541908; called by muse, mutect2, varscan2
- CDH19 | c.1841del p.L614* | Frame Shift Del (DEL) | VAF 21/114 reads (18%) | catalogued as rs1568168060; called by mutect2, pindel, varscan2
- CDH8 | c.2311del p.Q771Rfs*34 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as COSV100181544; called by mutect2, pindel*, varscan2
- CDK12 | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1220664561, COSV71003147; called by muse, mutect2
- CDKAL1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs866091749, COSV51191899; called by muse, varscan2
- CDYL | c.1057A>G p.T353A (on ENST00000328908 / NM_001368125.1; = p.T299A on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV59362142; called by muse, mutect2, varscan2
- CEACAM7 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 18/109 reads (17%) | catalogued as rs782719770, COSV50072867; called by muse, mutect2, varscan2
- CENPBD1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as rs761413813, COSV51921244; called by muse, mutect2, varscan2
- CENPC | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs775204684, COSV56626887; called by mutect2, varscan2
- CENPF | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV65279722; called by muse, mutect2, varscan2
- CENPF | c.6380G>A p.R2127H | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs776162995, COSV65275853; called by muse, mutect2, varscan2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 13/92 reads (14%) | catalogued as rs769310263; called by mutect2, pindel, varscan2
- CEP162 | c.2512G>T p.G838C | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57625365; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP54 | c.6011C>T p.A2004V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV61575931; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs778664468; called by pindel, varscan2
- CFAP65 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.277); catalogued as rs760655265, COSV58559669, COSV58562843; called by muse, varscan2
- CFAP94 | c.1387T>C p.W463R (on ENST00000320267 / NM_001352064.2; = p.W469R on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57237327; called by muse, mutect2, varscan2
- CFHR4 | c.1621del p.T541Qfs*30 (on ENST00000367416 / NM_001201551.2; = p.T295Qfs*30 on NM_006684.5) | Frame Shift Del (DEL) | VAF 26/142 reads (18%) | catalogued as rs780769494; called by mutect2, pindel, varscan2
- CHAD | c.423del p.L142Cfs*42 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as COSV51971952; called by mutect2, pindel, varscan2
- CHRM3 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55107703; called by muse, mutect2, varscan2
- CHRNB2 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63809608; called by muse, mutect2, varscan2
- CHST15 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.64); catalogued as rs772773156, COSV60560347, COSV60564258; called by mutect2, varscan2
- CIC | c.3512G>A p.R1171Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.733); catalogued as COSV50661235; called by muse, mutect2, varscan2
- CLCA2 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65289055; called by muse, mutect2, varscan2
- CLIP2 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140333329; called by muse, mutect2, varscan2
- CLVS2 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs760174151, COSV51561549, COSV51569371; called by muse, mutect2, varscan2
- CNGA3 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs770052346, COSV55624718; called by mutect2, varscan2
- CNNM4 | c.2213C>T p.T738I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100998608, COSV65662287; called by muse, mutect2, varscan2
- CNTNAP4 | c.3707T>C p.I1236T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV56703639; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as rs374805044; called by mutect2, varscan2
- COG2 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV64188651; called by muse, varscan2
- COG5 | c.2198C>T p.T733M (on ENST00000347053 / NM_001379512.1; = p.T754M on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs760602600, COSV51766287; called by muse, mutect2, varscan2
- COL6A6 | c.6238A>G p.R2080G | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62039498; called by muse, mutect2, varscan2
- COL9A1 | c.911del p.P304Rfs*24 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as COSV57893213; called by mutect2, pindel, varscan2
- COLGALT2 | c.474del p.K158Nfs*9 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | catalogued as rs1462551410; called by mutect2, pindel, varscan2
- COPB2 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.589); catalogued as COSV60351464; called by muse, mutect2, varscan2
- CORO1A | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs1206523159, COSV54632310; called by muse, mutect2, varscan2
- CPNE4 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 11/109 reads (10%) | catalogued as COSV70199078; called by muse, mutect2, varscan2
- CPNE6 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV53742574, COSV53747121; called by muse, varscan2
- CRAT | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs560724931, COSV100533977; called by mutect2, varscan2
- CREBBP | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.066); catalogued as rs758740001, COSV52143357; called by muse, mutect2, varscan2
- CRELD1 | c.1201A>G p.T401A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1476998585, COSV55978781; called by muse, mutect2, varscan2
- CRNKL1 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV100131580; called by muse, mutect2, varscan2
- CRTC2 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.768); catalogued as rs770068529, COSV57846041; called by muse, mutect2, varscan2
- CRYBG2 | c.3187C>A p.L1063I | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.303); catalogued as COSV100366956, COSV57490869; called by muse, mutect2, varscan2
- CSKMT | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs562358156, COSV63473661; called by muse, mutect2, varscan2
- CSMD1 | c.6028G>A p.G2010S (on ENST00000520002; = p.G2009S on NM_033225.6) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756922361, COSV59297555; called by muse, mutect2
- CSMD2 | c.7366C>T p.R2456W | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs200261592, COSV53903926; called by muse, mutect2, varscan2
- CSMD2 | c.4756G>A p.G1586R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs752801851, COSV53874849; called by muse, mutect2, varscan2
- CSMD3 | c.1804A>G p.T602A (on ENST00000297405 / NM_001363185.1; = p.T498A on NM_052900.3) | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV52198822, COSV52341199; called by muse, mutect2
- CSN3 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV59245140; called by muse, mutect2, varscan2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 16/138 reads (12%) | catalogued as rs767756120; called by mutect2, varscan2
- CTCFL | c.525A>T p.E175D | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as COSV54779981; called by muse, mutect2
- CTNNAL1 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 9/74 reads (12%) | catalogued as COSV57705934; called by muse, mutect2, varscan2
- CTR9 | c.2398G>T p.G800* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as COSV63729847; called by muse, mutect2, varscan2
- CUL9 | c.3317C>T p.T1106I | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV52735901; called by muse, mutect2, varscan2
- CX3CR1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1378630350, COSV64195603; called by muse, mutect2, varscan2
- CYGB | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs748501602, COSV53151602; called by mutect2, varscan2
- CYLC2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs199562230; called by mutect2, varscan2
- CYP27A1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761927223, COSV51470516; called by mutect2, varscan2
- CYP7B1 | c.392del p.N131Ifs*4 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as rs748480664, COSV59597772; called by mutect2, pindel, varscan2
- DAB1 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59738875; called by muse, mutect2, varscan2
- DAB2IP | c.1499G>T p.W500L (on ENST00000408936; = p.W472L on NM_032552.3) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV99405088; called by muse, varscan2
- DACT1 | c.508G>T p.G170* | Nonsense Mutation (SNP) | VAF 26/148 reads (18%) | catalogued as COSV60023897; called by muse, mutect2, varscan2
- DBNDD2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769957545, COSV100619523, COSV100619635; called by muse, mutect2, varscan2
- DCAF8L1 | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770928929, COSV71595462, COSV71595570; called by muse, mutect2, varscan2
- DCDC1 | c.4171C>T p.R1391W (on ENST00000597505 / NM_001367979.1; = p.R498W on NM_020869.3) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as rs144668195; called by muse, mutect2
- DCLRE1B | c.1464G>T p.K488N | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as COSV65813745; called by muse, mutect2, varscan2
- DCN | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs779618769, COSV50009791; called by muse, mutect2, varscan2
- DDX56 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV51835893; called by muse, mutect2, varscan2
- DDX60 | c.2573A>G p.Q858R | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV67099696; called by muse, mutect2, varscan2
- DENND3 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV52807647; called by muse, mutect2, varscan2
- DENND6A | c.1074dup p.A359Cfs*2 | Frame Shift Ins (INS) | VAF 11/72 reads (15%) | catalogued as rs34959359; called by mutect2, varscan2
- DEPTOR | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV53822840; called by muse, mutect2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DHH | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750409317, COSV57202979; called by muse, mutect2, varscan2
- DHRS9 | c.669del p.K223Nfs*25 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX8 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs199963654, COSV52257050; called by muse, mutect2, varscan2
- DIDO1 | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs374708890, COSV99825755; called by muse, mutect2, varscan2
- DISP3 | c.1341del p.T448Qfs*71 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | catalogued as COSV53825227; called by mutect2, pindel, varscan2
- DLAT | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs782632175, COSV54771819; called by muse, mutect2, varscan2
- DLGAP3 | c.2407C>T p.R803W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs776746778, COSV52391049; called by mutect2, varscan2
- DMD | c.7906A>C p.N2636H | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV58958508; called by muse, mutect2, varscan2
- DMTF1 | c.1244del p.N415Tfs*28 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | catalogued as rs1348399160; called by mutect2, pindel, varscan2
- DNAH5 | c.5198C>T p.S1733L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146087064; called by muse, varscan2
- DNAH8 | c.5446A>G p.T1816A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1043207748, COSV59485037; called by muse, mutect2, varscan2
- DNAH9 | c.9856C>T p.R3286C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs990212558, COSV52342960; called by muse, mutect2
- DNAH9 | c.10340G>A p.R3447H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769435149, COSV52361311; called by muse, mutect2, varscan2
- DNAH9 | c.11520G>T p.Q3840H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52380515; called by muse, mutect2, varscan2
- DNAJC22 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs775389117, COSV67712621; called by muse, mutect2, varscan2
- DOCK10 | c.6204G>T p.K2068N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51430187; called by muse, mutect2, varscan2
- DOCK10 | c.2608del p.R870Efs*21 | Frame Shift Del (DEL) | VAF 30/180 reads (17%) | catalogued as rs1559535685; called by mutect2, varscan2
- DOLK | c.1556A>G p.Y519C | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV58282939; called by muse, mutect2, varscan2
- DPEP2 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs370389022, COSV52056293; called by muse, mutect2
- DPH7 | c.460del p.T154Lfs*9 | Frame Shift Del (DEL) | VAF 35/200 reads (18%) | catalogued as COSV53021323; called by mutect2, pindel, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 34/260 reads (13%) | catalogued as rs1475611014; called by mutect2, pindel, varscan2
- DSCAML1 | c.422C>T p.T141M (on ENST00000321322; = p.T81M on NM_020693.4) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478726901, COSV58404411; called by muse, mutect2, varscan2
- DST | c.17223del p.K5741Nfs*2 (on ENST00000361203 / NM_001374722.1; = p.K3438Nfs*2 on NM_015548.5) | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs756726565; called by mutect2, varscan2
- DTX3 | c.329del p.G110Vfs*86 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs1288891994; called by mutect2, pindel
- DUOX2 | c.4232G>A p.C1411Y | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs766067391, CM1310010, COSV66535142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUS1L | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs768534602, COSV57651771; called by mutect2, varscan2
- DUS4L-BCAP29 | c.1060dup p.W354Lfs*25 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | catalogued as rs746928635; called by mutect2, varscan2
- DUSP6 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 19/93 reads (20%) | catalogued as COSV54379676; called by muse, mutect2, varscan2
- DYNC1H1 | c.9142G>A p.E3048K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1555410941, CM142947, COSV64143770; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.8871G>T p.K2957N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV62088613; called by muse, mutect2, varscan2
- E2F7 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs762356959, COSV59737409; called by muse, mutect2, varscan2
- E2F8 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1343175254, COSV100001753, COSV51465820; called by muse, mutect2, varscan2
- EDIL3 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56924916; called by muse, mutect2, varscan2
- EEF1AKMT4 | c.696del p.R233Dfs*65 | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | catalogued as rs780984426, COSV56182176; called by mutect2, pindel, varscan2
- EFCAB1 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.379); catalogued as rs759021627, COSV50618291; called by mutect2, varscan2
- EGFL8 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as rs781035335, COSV61248818; called by muse, mutect2, varscan2
- EHMT2 | c.2448+1G>A p.X816_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as rs757379655, COSV64998284; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF4A2 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV56218950; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as rs542493499, COSV57518488; called by mutect2, varscan2
- EIF5 | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53687044; called by muse, mutect2
- ELK4 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99222299; called by muse, mutect2, varscan2
- EP300 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54347041; called by muse, mutect2, varscan2
- EP300 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs983340187, COSV54332013; called by muse, mutect2, varscan2
- EPHA2 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.302); catalogued as rs754988701, COSV64454544, COSV64454984; called by muse, mutect2, varscan2
- EPHX3 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs748210176, COSV55656859; called by mutect2, varscan2
- EPPIN-WFDC6 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs771646708, COSV60547967; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | catalogued as rs753821453; called by mutect2, varscan2
- ESF1 | c.512del p.N171Tfs*18 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs745713173; called by mutect2, varscan2
- ESPL1 | c.3712C>A p.P1238T | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV57763939; called by muse, mutect2, varscan2
- ESPL1 | c.4253G>A p.R1418Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs531311020, COSV57763957; called by muse, mutect2, varscan2
- ETV5 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs779639231, COSV60501408; called by muse, mutect2
- EVC | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53838952; called by muse, mutect2
- EVL | c.109A>G p.N37D (on ENST00000402714 / NM_001330221.2; = p.N39D on NM_016337.3) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV67377366; called by muse, mutect2, varscan2
- EXOG | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55064947; called by muse, mutect2, varscan2
- EXOSC10 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451503673, COSV58668462; called by muse, mutect2, varscan2
- EXTL2 | c.638T>A p.I213N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV64473793; called by muse, mutect2, varscan2
- EYA4 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.146); catalogued as rs776409783, COSV62061747; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F11 | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.263); catalogued as COSV53010097; called by muse, mutect2
- F13A1 | c.1123T>C p.C375R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53569078; called by muse, mutect2, varscan2
- F7 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747989049, CM051920, CM073037, COSV60646194, COSV60647098; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM161A | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.88); catalogued as COSV56768062; called by muse, mutect2, varscan2
- FAM170A | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs576282871, COSV58927528, COSV58927620; called by muse, mutect2, varscan2
- FAM186B | c.1978_1980del p.K660del | In Frame Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs777861400; called by pindel, varscan2
- FAM193A | c.1236T>A p.C412* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV61199455; called by muse, mutect2, varscan2
- FAM91A1 | c.2383C>A p.L795I | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV58240246; called by muse, mutect2, varscan2
- FANCC | c.1468C>T p.L490F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56668256; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | catalogued as rs746983128; called by mutect2, varscan2
- FAR2 | c.529del p.I177Sfs*8 | Frame Shift Del (DEL) | VAF 20/113 reads (18%) | catalogued as rs757443519; called by mutect2, varscan2
- FAT4 | c.8188G>A p.V2730I | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs369228145; called by muse, mutect2, varscan2
- FAT4 | c.12356C>T p.P4119L | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58701077, COSV58712338; called by muse, mutect2, varscan2
- FBXL22 | c.65_67del p.S22del | In Frame Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs757568276; called by mutect2, pindel, varscan2
- FBXO10 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs771838111, COSV52836153; called by muse, mutect2, varscan2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs772635228; called by mutect2, varscan2
- FBXO30 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV52792704; called by muse, mutect2, varscan2
- FCRL3 | c.1366G>T p.G456C | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63845475; called by muse, mutect2, varscan2
- FGF5 | c.441del p.G148Efs*45 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs35667286; called by pindel, varscan2
- FGFBP2 | c.601_603del p.K201del | In Frame Del (DEL) | VAF 12/57 reads (21%) | catalogued as rs771509081; called by pindel, varscan2
- FHDC1 | c.2707C>T p.R903C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373342133; called by muse, mutect2, varscan2
- FHL2 | c.74G>T p.S25I | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV59080714; called by muse, mutect2, varscan2
- FKBP3 | c.90G>T p.Q30H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV53534057; called by muse, mutect2, varscan2
- FKBP9 | c.261del p.G88Dfs*3 | Frame Shift Del (DEL) | VAF 26/159 reads (16%) | catalogued as COSV54228581; called by mutect2, pindel, varscan2
- FLNC | c.3380G>A p.G1127D | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57966486; called by muse, mutect2, varscan2
- FLNC | c.3854G>A p.G1285D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100367838; called by muse, mutect2, varscan2
- FMN1 | c.3529G>A p.V1177M (on ENST00000616417 / NM_001277313.2; = p.V954M on NM_001103184.4) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771076405, COSV57935144; called by muse, mutect2, varscan2
- FNBP1L | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774614978, COSV53091412; called by muse, mutect2, varscan2
- FNDC7 | c.2006C>T p.T669M | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs200104300, COSV54751789; called by muse, mutect2, varscan2
- FNTB | c.1047del p.L350Ffs*18 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as rs768774237; called by pindel, varscan2
- FOXP4 | c.1475A>G p.E492G (on ENST00000307972 / NM_001012426.1; = p.E479G on NM_138457.3) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57224244; called by muse, mutect2, varscan2
- FRAS1 | c.10319C>A p.T3440N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.603); catalogued as COSV53654540; called by muse, mutect2, varscan2
- FSHR | c.1922T>C p.L641P | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58636822; called by muse, mutect2, varscan2
- FTSJ3 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV63791599; called by muse, mutect2, varscan2
- FZD7 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV53811758; called by mutect2, varscan2
- GABARAPL1 | c.289-1G>A p.X97_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV56771697; called by muse, mutect2, varscan2
- GABRA4 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51921853; called by muse, mutect2, varscan2
- GABRB2 | c.1474C>T p.R492C (on ENST00000274547; = p.R454C on NM_000813.3) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50909148; called by muse, mutect2, varscan2
- GAK | c.2698G>C p.A900P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV58510674; called by muse, varscan2
- GAK | c.2465A>G p.D822G | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as COSV58510681; called by muse, mutect2, varscan2
- GALNT1 | c.113del p.K38Rfs*11 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as rs1225897793; called by mutect2, pindel, varscan2
- GALNT1 | c.186del p.K63Nfs*13 | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | catalogued as COSV99322192; called by mutect2, pindel, varscan2
- GALNT17 | c.975G>T p.M325I | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.262); catalogued as COSV100353177; called by mutect2, varscan2
- GALR1 | c.1048T>C p.*350Rext*1 | Nonstop Mutation (SNP) | VAF 18/120 reads (15%) | catalogued as COSV55319452; called by muse, varscan2
- GAP43 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV59348975; called by muse, mutect2
- GASK1B | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); catalogued as COSV56712342; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 26/140 reads (19%) | catalogued as rs548474277; called by mutect2, varscan2
- GBP7 | c.1293dup p.H432Afs*12 | Frame Shift Ins (INS) | VAF 25/156 reads (16%) | catalogued as rs754177800; called by mutect2, varscan2
- GCC2 | c.2755C>T p.R919* | Nonsense Mutation (SNP) | VAF 21/113 reads (19%) | catalogued as COSV59175073; called by muse, mutect2, varscan2
- GCN1 | c.4225G>A p.G1409S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56110388; called by muse, mutect2, varscan2
- GDAP2 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1246275688, COSV65613516; called by muse, mutect2, varscan2
- GDAP2 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65613523; called by muse, mutect2, varscan2
- GDPD5 | c.1462del p.L488Sfs*48 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as COSV100409095; called by mutect2, pindel, varscan2
- GEM | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs769234376, COSV52596968; called by muse, mutect2, varscan2
- GEMIN2 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as rs1456512934, COSV51629962; called by muse, mutect2, varscan2
- GGA1 | c.1255G>A p.G419S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.048); catalogued as rs150957887; called by mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs750227570; called by mutect2, varscan2
- GLG1 | c.2854G>A p.G952S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs761056314, COSV52672790, COSV52674389; called by muse, mutect2, varscan2
- GLRA3 | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56858400; called by muse, mutect2, varscan2
- GLRB | c.1068C>G p.N356K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV52423261; called by muse, mutect2, varscan2
- GLT8D1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 20/137 reads (15%) | catalogued as rs780919696, COSV56477640; called by muse, mutect2, varscan2
- GLYATL2 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV54851817; called by muse, mutect2, varscan2
- GNPDA1 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.1); catalogued as rs767475273, COSV60942343, COSV60943345; called by muse, mutect2, varscan2
- GOLGA5 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs777041385, COSV50833661; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | catalogued as rs370114090; called by mutect2, varscan2
- GPATCH1 | c.2766-2A>C p.X922_splice | Splice Site (SNP) | VAF 12/108 reads (11%) | catalogued as COSV50130063; called by muse, mutect2, varscan2
- GPATCH4 | c.629del p.K210Rfs*73 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | catalogued as rs754640631; called by mutect2, varscan2
- GPHN | c.809C>T p.S270L (on ENST00000315266 / NM_001377519.1; = p.S303L on NM_020806.5) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.921); catalogued as rs1064796317, COSV59495304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPHN | c.1265A>G p.D422G (on ENST00000315266 / NM_001377519.1; = p.D455G on NM_020806.5) | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV59495312; called by muse, mutect2, varscan2
- GPR108 | c.985G>A p.V329I (on ENST00000264080 / NM_001080452.1; = p.V87I on NM_020171.2) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.123); catalogued as rs771574245, COSV51188318; called by mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 34/166 reads (20%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPSM3 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs550485790, COSV66684447; called by muse, varscan2
- GRAMD1A | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV58769311; called by mutect2, varscan2
- GRAMD1C | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV63984820; called by muse, mutect2, varscan2
- GREB1 | c.3536C>T p.P1179L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52197809; called by muse, mutect2
- GREB1 | c.4871G>A p.R1624Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs749186312, COSV52197817, COSV99303809; called by muse, mutect2, varscan2
- GRIA1 | c.2618G>T p.G873V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV53590482, COSV53627793; called by muse, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | catalogued as rs760757380; called by mutect2, varscan2
- GRM7 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs150165030; called by muse, mutect2, varscan2
- GUCA1A | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs745750078, COSV50004497; called by muse, mutect2, varscan2
- GUCD1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1026748860, COSV68035671; called by muse, mutect2, varscan2
- H1-1 | c.513del p.K171Nfs*5 | Frame Shift Del (DEL) | VAF 20/218 reads (9%) | catalogued as COSV55119441; called by mutect2, pindel
- H2BC13 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV62440462, COSV62441065; called by muse, mutect2, varscan2
- H2BC15 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 53/301 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV57586725; called by muse, mutect2, varscan2
- H6PD | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66232564; called by muse, mutect2, varscan2
- HABP2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs529346597, COSV63637721; called by muse, mutect2, varscan2
- HAS2 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 16/155 reads (10%) | catalogued as COSV58265301; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HCRTR1 | c.44del p.P15Lfs*63 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs768602707; called by mutect2, pindel
- HDAC5 | c.3179G>A p.C1060Y | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs533094138, COSV52244036; called by muse, mutect2, varscan2
- HEATR6 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs769447556, COSV51749516; called by muse, mutect2, varscan2
- HEATR6 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs564661662, COSV51749533; called by muse, varscan2
- HECA | c.1004del p.G335Dfs*27 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs771658394; called by pindel, varscan2
- HECTD1 | c.5351G>A p.R1784H | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs757207097, COSV67948037; called by muse, varscan2
- HECTD2 | c.1144del p.I382Sfs*11 | Frame Shift Del (DEL) | VAF 12/97 reads (12%) | catalogued as rs57105282; called by mutect2, varscan2
- HECW2 | c.2763del p.V922* | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | catalogued as COSV99646682; called by mutect2, pindel, varscan2
- HELZ2 | c.4013G>A p.R1338H (on ENST00000467148 / NM_001037335.2; = p.R769H on NM_033405.3) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as rs1050997322, COSV71297120; called by muse, mutect2, varscan2
- HEPACAM2 | c.304C>T p.P102S (on ENST00000394468 / NM_001039372.4; = p.P90S on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.626); catalogued as rs374504388; called by muse, mutect2, varscan2
- HERC1 | c.14196G>T p.E4732D | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV71250683, COSV71250735; called by muse, mutect2, varscan2
- HERC1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs769145958, COSV71250686; called by muse, mutect2, varscan2
- HERC2 | c.14305C>T p.P4769S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55322052; called by muse, mutect2, varscan2
- HERC2 | c.13201C>T p.R4401W | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762578420, COSV55328037; called by muse, mutect2, varscan2
- HERC5 | c.287dup p.N96Kfs*25 | Frame Shift Ins (INS) | VAF 23/114 reads (20%) | catalogued as rs1403833438; called by mutect2, pindel, varscan2
- HFM1 | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as COSV99645733; called by muse, mutect2, varscan2
- HIPK3 | c.1300dup p.C434Lfs*20 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | catalogued as rs761758734; called by mutect2, varscan2
- HJURP | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1559496473, COSV64979687; called by muse, mutect2, varscan2
- HMCN1 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54946987; called by muse, mutect2, varscan2
- HMCN1 | c.12349C>T p.R4117C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs777001625, COSV54873921; called by muse, mutect2, varscan2
- HMCN1 | c.14177G>A p.G4726D | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs149329415, COSV54945702; called by muse, mutect2, varscan2
- HMGCR | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55318382; called by muse, mutect2, varscan2
- HPCAL4 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV65716462; called by muse, mutect2, varscan2
- HSP90AB1 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as COSV100807024; called by muse, mutect2, varscan2
- HSPA4L | c.1722del p.G575Efs*18 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | catalogued as rs775794446; called by mutect2, pindel, varscan2
- ICAM1 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763586600, COSV53427637; called by muse, mutect2, varscan2
- IGF2BP2 | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs750722399, COSV100648967; called by mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs760021495; called by mutect2, varscan2
- IGHV3-48 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.221); catalogued as rs1555530768; called by muse, mutect2
- IGLV3-27 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | catalogued as rs751481735; called by mutect2, pindel, varscan2
- IGSF11 | c.1225G>A p.A409T (on ENST00000393775 / NM_001015887.3; = p.A408T on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs769083075, COSV61171561; called by muse, mutect2, varscan2
- IGSF3 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs577348152, COSV59599564; called by muse, mutect2, varscan2
- IKZF2 | c.300A>C p.Q100H | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.26); catalogued as COSV59585003; called by muse, mutect2, varscan2
- IL17RD | c.1452C>A p.C484* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV56343605; called by muse, mutect2, varscan2
- IL22RA1 | c.1007A>G p.Q336R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54630686; called by muse, mutect2, varscan2
- IL4R | c.679del p.E227Sfs*51 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as COSV50150686, COSV99405139; called by mutect2, pindel, varscan2
- ILKAP | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV54520586; called by muse, mutect2, varscan2
- INA | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63976696; called by muse, mutect2, varscan2
- INHA | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs777288649, COSV54730966; called by muse, mutect2, varscan2
- INO80D | c.2070A>G p.I690M | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV68960290; called by muse, mutect2
- INPP5F | c.631del p.W211Gfs*5 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs768918635; called by mutect2, pindel, varscan2
- INPP5F | c.2211G>A p.M737I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV62824283; called by muse, mutect2, varscan2
- INVS | c.1748T>C p.M583T | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52451416, COSV99318565; called by muse, mutect2, varscan2
- ITFG2 | c.55T>G p.F19V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99958091; called by muse, mutect2, varscan2
- ITGA2 | c.2553dup p.A852Cfs*8 | Frame Shift Ins (INS) | VAF 30/232 reads (13%) | catalogued as rs1442857013; called by mutect2, pindel, varscan2
- ITGA4 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV52004896; called by muse, mutect2, varscan2
- ITGA4 | c.2883+1G>A p.X961_splice | Splice Site (SNP) | VAF 7/45 reads (16%) | catalogued as rs188628120, COSV59211583; called by mutect2, varscan2
- ITGAE | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs781000850, COSV54000876; called by muse, mutect2, varscan2
- ITGAX | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs200320931, COSV51643641; called by muse, mutect2, varscan2
- ITIH4 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56579556; called by mutect2, varscan2
- ITPR3 | c.146dup p.K50* | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | catalogued as rs1561853447; called by mutect2, pindel, varscan2
- ITPR3 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100966789, COSV65407322; called by muse, mutect2, varscan2
- ITPRID1 | c.50A>G p.E17G | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as COSV60084320; called by muse, mutect2, varscan2
- ITSN1 | c.147del p.Q50Nfs*9 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | catalogued as rs746959118; called by mutect2, varscan2
- IVNS1ABP | c.1096A>G p.M366V | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62252293; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JMY | c.1718A>G p.Y573C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs762180475, COSV68662716; called by muse, mutect2, varscan2
- KANSL1 | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.087); catalogued as COSV52275030; called by muse, mutect2, varscan2
- KAT6B | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs568525923, COSV54741444; called by muse, mutect2, varscan2
- KATNIP | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV55193362; called by muse, mutect2, varscan2
- KCNA6 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54977123, COSV54978611; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNC4 | c.1546del p.R516Gfs*17 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | catalogued as rs766560714; called by pindel, varscan2
- KCNJ1 | c.907T>C p.S303P | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.908); catalogued as COSV60663179; called by muse, mutect2, varscan2
- KCNJ15 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as COSV60810899; called by muse, mutect2, varscan2
- KCNJ3 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54546077; called by muse, mutect2, varscan2
- KCNQ5 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs866590945, COSV100572979, COSV59667758; called by muse, mutect2, varscan2
- KCTD21 | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV60741908; called by muse, mutect2, varscan2
- KDM1A | c.2383C>T p.R795* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as rs746295431, COSV56500117; called by muse, mutect2, varscan2
- KDM4A | c.1630G>A p.V544M | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV64961025; called by muse, mutect2, varscan2
- KDM4B | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50209005; called by muse, mutect2, varscan2
- KDM4D | c.278del p.K93Rfs*4 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | catalogued as rs142280183; called by mutect2, varscan2
- KDM6B | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV54687905; called by muse, mutect2, varscan2
- KIAA1109 | c.1205del p.N402Ifs*9 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as COSV52685780; called by mutect2, varscan2
- KIF18A | c.2522C>T p.S841L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs369809315; called by muse, mutect2, varscan2
- KIF1A | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1225233710, COSV57494506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIFAP3 | c.607del p.C203Vfs*22 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs1380692252; called by mutect2, pindel
- KLF15 | c.977C>A p.P326H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56181289; called by muse, mutect2, varscan2
- KLHL22 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs373085414; called by mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 19/121 reads (16%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KMT2D | c.7001G>A p.R2334Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs757300574, COSV56492816, COSV56498083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KNTC1 | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.213); catalogued as rs757801099, COSV61085067; called by mutect2, varscan2
- KRBA2 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs200739857, COSV58779909; called by muse, mutect2, varscan2
- KRT74 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59772973; called by muse, mutect2, varscan2
- KRT75 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV52875590; called by muse, mutect2, varscan2
- LARP1B | c.2361del p.K787Nfs*26 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as rs758463950; called by mutect2, varscan2
- LARS2 | c.1073T>A p.V358D | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV55532800; called by muse, mutect2, varscan2
- LHX2 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.056); catalogued as COSV65319280; called by muse, mutect2, varscan2
- LIFR | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV54701507; called by muse, mutect2, varscan2
- LIM2 | c.424C>A p.L142M (on ENST00000596399 / NM_001161748.2; = p.L184M on NM_030657.4) | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.208); catalogued as COSV55741065, COSV55742634; called by muse, mutect2, varscan2
- LMNTD1 | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51451318; called by muse, mutect2, varscan2
- LRBA | c.3570G>A p.M1190I | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV63966574; called by muse, mutect2, varscan2
- LRGUK | c.1859A>G p.H620R | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV53644885; called by muse, mutect2, varscan2
- LRP1B | c.10342C>T p.H3448Y | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as COSV67281511; called by muse, mutect2, varscan2
- LRP3 | c.1693G>A p.V565M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1429065035, COSV53507909; called by muse, mutect2, varscan2
- LRRC14 | c.268C>A p.L90M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.73); catalogued as COSV52881582, COSV52883346; called by muse, mutect2, varscan2
- LRRC37B | c.2099C>T p.T700M | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760591432, COSV58951271, COSV58954067; called by muse, mutect2, varscan2
- LRRC43 | c.1326T>A p.D442E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV60293923; called by muse, mutect2, varscan2
- LRRC47 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1310480048, COSV65563092; called by muse, varscan2
- LRTM2 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54566950; called by muse, mutect2, varscan2
- LTA | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.998); catalogued as COSV69304518; called by muse, mutect2, varscan2
- LTBP2 | c.886C>A p.R296S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV56214985; called by muse, mutect2, varscan2
- LYPD6B | c.386C>T p.T129M (on ENST00000409029 / NM_001317004.1; = p.T153M on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); catalogued as rs755730639, COSV54521125; called by muse, mutect2, varscan2
- MADD | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as COSV60630316; called by muse, mutect2, varscan2
- MAGEL2 | c.3430C>T p.R1144W | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.555); catalogued as rs1170449979, COSV58569210, COSV58569511; called by muse, mutect2, varscan2
- MAGI3 | c.318C>T p.G106= | Splice Region (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100288524; called by muse, varscan2
- MAMLD1 | c.1207A>G p.M403V | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV53381689; called by muse, mutect2, varscan2
- MANSC1 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | catalogued as COSV67111580; called by muse, mutect2, varscan2
- MAP1B | c.5901dup p.E1968Rfs*8 | Frame Shift Ins (INS) | VAF 15/98 reads (15%) | catalogued as rs775893760; called by mutect2, varscan2
- MAP1B | c.6638G>A p.R2213H | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as rs754794035, COSV57100897; called by muse, mutect2, varscan2
- MAP2K3 | c.51A>G p.G17= | Splice Region (SNP) | VAF 22/210 reads (10%) | catalogued as rs1029407665, COSV100383645; called by muse, mutect2
- MAP3K3 | c.536del p.P179Lfs*39 | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | catalogued as COSV62281838; called by mutect2, pindel, varscan2
- MAP3K7 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV65226286; called by muse, mutect2
- MAP3K9 | c.1555A>G p.S519G | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67123134; called by muse, varscan2
- MBD4 | c.939del p.E314Kfs*4 | Frame Shift Del (DEL) | VAF 30/109 reads (28%) | catalogued as rs558765093; called by mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | catalogued as rs749738168; called by pindel, varscan2
- MBD6 | c.2212C>A p.P738T | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63076801; called by muse, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 38/226 reads (17%) | catalogued as rs750092100; called by mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs773080349; called by mutect2, varscan2
- MED15 | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV53034196; called by muse, mutect2, varscan2
- MEGF10 | c.2569G>A p.G857R | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs748159770, COSV57257500; called by muse, mutect2, varscan2
- MGMT | c.347A>G p.H116R (on ENST00000306010; = p.H85R on NM_002412.5) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV60035999; called by muse, mutect2, varscan2
- MICU1 | c.554G>A p.R185Q (on ENST00000361114 / NM_001195518.2; = p.R191Q on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.417); catalogued as COSV63148327; called by muse, mutect2
- MIEF1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs904510879, COSV57480967; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 26/147 reads (18%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MIP | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57515882; called by muse, mutect2
- MITD1 | c.723del p.H242Ifs*12 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | catalogued as COSV56806554; called by mutect2, pindel, varscan2
- MKRN3 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV58812616; called by muse, mutect2, varscan2
- MLF2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.067); catalogued as COSV52572289; called by muse, mutect2, varscan2
- MOCS1 | c.277del p.V93Sfs*3 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as COSV57940023; called by mutect2, pindel, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs757379917; called by mutect2, varscan2
- MPP3 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs752209290, COSV68199421; called by muse, mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 26/147 reads (18%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRPL16 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as rs746870214, COSV55698374; called by muse, mutect2, varscan2
- MRPS7 | c.453C>A p.N151K | Missense Mutation (SNP) | VAF 75/453 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55454534; called by muse, mutect2, varscan2
- MST1R | c.2572C>T p.R858C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs751338048, COSV56570951; called by muse, mutect2, varscan2
- MTHFD1L | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.898); catalogued as COSV66223762; called by muse, mutect2, varscan2
- MTSS1 | c.459del p.R155Efs*34 | Frame Shift Del (DEL) | VAF 30/198 reads (15%) | catalogued as rs1563799887; called by mutect2, pindel, varscan2
- MUC16 | c.38865A>C p.K12955N | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.351); catalogued as COSV67499404; called by muse, mutect2, varscan2
- MUC16 | c.4480A>G p.T1494A | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); catalogued as rs776377933, COSV67499411; called by muse, mutect2, varscan2
- MUTYH | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs373766973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MVB12B | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs755037370, COSV63261504; called by muse, mutect2, varscan2
- MYBBP1A | c.2741A>C p.Q914P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV54605256; called by muse, mutect2
- MYBBP1A | c.2192G>A p.S731N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1391690602, COSV54605280; called by muse, mutect2, varscan2
- MYCBP2 | c.10439C>T p.P3480L (on ENST00000357337; = p.P3518L on NM_015057.5) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746210833, COSV62042115; called by mutect2, varscan2
- MYD88 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); catalogued as COSV57181459; called by muse, mutect2, varscan2
- MYG1 | c.851C>A p.S284Y | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV99266880; called by muse, mutect2, varscan2
- MYH10 | c.4298C>T p.T1433M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as rs539038765, COSV52613065; called by muse, mutect2, varscan2
- MYH13 | c.2467C>A p.R823S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV52823349, COSV52845301; called by mutect2, varscan2
- MYH9 | c.2774A>T p.E925V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV53381635; called by muse, mutect2, varscan2
- MYNN | c.968T>A p.I323K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62992447; called by muse, mutect2, varscan2
- MYO10 | c.3496C>T p.R1166C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV57030944; called by muse, mutect2, varscan2
- MYO10 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV72563787; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO3B | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58720310; called by muse, mutect2, varscan2
- MYOCD | c.2110T>C p.S704P | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV58513728; called by muse, mutect2, varscan2
- MYOF | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as rs374976050; called by muse, mutect2, varscan2
- MYOZ3 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51739785; called by muse, mutect2, varscan2
- NAA15 | c.1841del p.N614Mfs*22 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as rs1283385686, COSV56718069; called by mutect2, varscan2
- NAALADL2 | c.770A>G p.Q257R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV101458172; called by muse, varscan2
- NAB2 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV100272602, COSV55668241; called by muse, mutect2
- NALCN | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); catalogued as COSV51918548, COSV51958922; called by muse, mutect2
- NBAS | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs555950436, COSV55740205; called by muse, mutect2, varscan2
- NBPF3 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs201079583, COSV59058372; called by muse, mutect2, varscan2
- NCDN | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV61936311; called by muse, mutect2, varscan2
- NCOA1 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56054332; called by muse, mutect2, varscan2
- NCOA2 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178904391, COSV71765094; called by muse, varscan2
- NCOA6 | c.513A>G p.P171= | Splice Region (SNP) | VAF 17/136 reads (13%) | catalogued as COSV62868625; called by muse, mutect2, varscan2
- NCOA7 | c.209del p.K70Rfs*7 | Frame Shift Del (DEL) | VAF 36/304 reads (12%) | catalogued as rs749319230; called by mutect2, varscan2
- NDUFAF6 | c.605A>G p.H202R | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99712669; called by muse, mutect2, varscan2
- NDUFS2 | c.1145T>G p.F382C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57156373; called by muse, mutect2
- NECAP1 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs764080699, COSV60250272; called by muse, mutect2, varscan2
- NEFL | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.31); catalogued as COSV55338357; called by muse, mutect2, varscan2
- NEK2 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as rs776935855, COSV65357430; called by muse, mutect2, varscan2
- NEK5 | c.2067C>G p.S689R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.007); catalogued as COSV62879627, COSV62882274; called by muse, mutect2
- NELFCD | c.791G>A p.G264D (on ENST00000602795; = p.G246D on NM_198976.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373372450, COSV59745493; called by mutect2, varscan2
- NFATC4 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as COSV51599431; called by muse, mutect2, varscan2
- NFE2L1 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62583855; called by muse, mutect2, varscan2
- NIBAN2 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs760512238, COSV64825794; called by mutect2, varscan2
- NID2 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV53493688; called by muse, mutect2, varscan2
- NID2 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs1303483218, COSV53503896; called by muse, mutect2
- NIN | c.5404G>T p.E1802* (on ENST00000382041 / NM_182946.1; = p.E1089* on NM_016350.4) | Nonsense Mutation (SNP) | VAF 42/178 reads (24%) | catalogued as COSV55408985; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 16/114 reads (14%) | catalogued as rs145147241; called by mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 26/246 reads (11%) | catalogued as rs763440516; called by mutect2, varscan2
- NNMT | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as rs1202764623, COSV55475210; called by muse, mutect2, varscan2
- NOL10 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as rs749214861, COSV62038825; called by mutect2, varscan2
- NOS1 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100500311; called by mutect2, varscan2
- NOTCH4 | c.4036C>T p.R1346W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs911402506, COSV66680932, COSV66682188; called by muse, mutect2, varscan2
- NPBWR2 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.928); catalogued as rs756986251, COSV63900686; called by muse, mutect2
- NPFFR1 | c.250A>G p.N84D | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53335334; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs774343392; called by mutect2, varscan2
- NRG3 | c.1141T>C p.F381L | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.067); catalogued as COSV64587656; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as rs776154715; called by mutect2, varscan2
- NRIP1 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.173); catalogued as COSV59660503, COSV59661364; called by mutect2, varscan2
- NRXN2 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as rs1427232278, COSV55449452, COSV99633149; called by muse, mutect2, varscan2
- NSD1 | c.4759C>T p.R1587C | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as rs764613088, COSV61786146; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSG2 | c.325-1G>A p.X109_splice | Splice Site (SNP) | VAF 13/76 reads (17%) | catalogued as COSV57460116; called by muse, mutect2, varscan2
- NT5C2 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs558105444, COSV58419821; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NTRK1 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1292790967, COSV62324793; called by muse, mutect2, varscan2
- NUDT12 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1164800828, COSV50093368; called by muse, varscan2
- NUP107 | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57498672; called by muse, mutect2, varscan2
- NUP210 | c.2879A>G p.D960G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768107728, COSV99595893; called by mutect2, varscan2
- NXN | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs370296358; called by muse, mutect2, varscan2
- OAF | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1183187871, COSV61110100; called by muse, mutect2, varscan2
- ODF2 | c.107C>A p.P36H (on ENST00000434106 / NM_153433.2; = p.P80H on NM_153432.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV63549253; called by muse, mutect2, varscan2
- ODF3L1 | c.515C>A p.P172H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59820675; called by muse, mutect2, varscan2
- OGA | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs983038298, COSV63383659; called by muse, mutect2, varscan2
- OGDH | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV56058124; called by muse, mutect2, varscan2
- OGFRL1 | c.1277A>G p.N426S | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV64972582; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR13A1 | c.929T>C p.L310S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65573650; called by muse, mutect2, varscan2
- OR2B6 | c.673G>C p.V225L | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV55129921; called by muse, mutect2, varscan2
- OR4C15 | c.529G>A p.V177M (on ENST00000314644; = p.V123M on NM_001001920.2) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV58956199; called by muse, mutect2, varscan2
- OR4D9 | c.455del p.G152Afs*6 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | catalogued as rs774793470; called by mutect2, pindel, varscan2
- OR52A5 | c.194del p.L65Wfs*20 | Frame Shift Del (DEL) | VAF 8/89 reads (9%) | catalogued as rs762677866, COSV100263457; called by mutect2, varscan2
- OR5D16 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65723119; called by muse, mutect2, varscan2
- OR5L1 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.275); catalogued as rs1251625791, COSV61735650; called by muse, varscan2
- OR5M10 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1380619380, COSV73242261; called by muse, mutect2, varscan2
- OR5M8 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV59116362, COSV59116547; called by muse, mutect2, varscan2
- OR7D2 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.803); catalogued as rs369973889; called by muse, mutect2, varscan2
- OR8G1 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100422328; called by muse, mutect2, varscan2
- OR8U1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs760842398, COSV100163833; called by muse, varscan2
- OR9A2 | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63307186; called by muse, mutect2, varscan2
- OR9A4 | c.535del p.C179Vfs*23 | Frame Shift Del (DEL) | VAF 58/196 reads (30%) | catalogued as rs562194466; called by mutect2, varscan2
- OSBPL2 | c.550G>A p.A184T (on ENST00000313733 / NM_144498.4; = p.A172T on NM_014835.4) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs747912454, COSV58220406; called by muse, mutect2, varscan2
- OSMR | c.1849del p.T617Qfs*20 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | catalogued as rs762315064; called by mutect2, pindel
- OTOGL | c.5977C>G p.Q1993E (on ENST00000547103; = p.Q1984E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100086998; called by muse, mutect2, varscan2
- OTOP1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs200612216; called by muse, mutect2, varscan2
- OTUB2 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.619); catalogued as COSV52574801, COSV99180162; called by muse, mutect2, varscan2
- PACC1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.301); catalogued as rs370542732, COSV54786723; called by muse, mutect2
- PAGE1 | c.25T>C p.Y9H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.588); catalogued as COSV65998725, COSV65998947; called by muse, mutect2, varscan2
- PAK2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 32/229 reads (14%) | catalogued as COSV59086172; called by muse, mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 51/337 reads (15%) | catalogued as rs751755759; called by mutect2, pindel, varscan2
- PAN3 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as COSV56707925; called by muse, mutect2, varscan2
- PAPPA2 | c.3361T>C p.S1121P | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV62813811; called by muse, mutect2, varscan2
- PARD3B | c.646C>G p.H216D | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV62533501; called by muse, mutect2, varscan2
- PARVB | c.700A>G p.M234V | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV58692184; called by muse, mutect2, varscan2
- PASK | c.2159C>T p.T720M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs767264831, COSV52162135; called by mutect2, varscan2
- PAX1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.713); catalogued as COSV68272398; called by muse, mutect2, varscan2
- PCDH10 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52105566; called by muse, mutect2, varscan2
- PCDH7 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV62344191; called by mutect2, varscan2
- PCDH7 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.185); catalogued as rs1471621727, COSV62336069; called by muse, mutect2
- PCDHA13 | c.2189G>A p.G730D | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV56530053; called by muse, mutect2, varscan2
- PCDHA3 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.223); catalogued as COSV63539162; called by muse, mutect2, varscan2
- PCDHA5 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); catalogued as rs140039635; called by muse, mutect2, varscan2
- PCDHA6 | c.2050G>A p.V684M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.132); catalogued as COSV65348178; called by muse, mutect2, varscan2
- PCDHB11 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV53384643; called by muse, mutect2, varscan2
- PCDHB11 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.403); catalogued as COSV61309711; called by muse, mutect2, varscan2
- PCDHGA11 | c.1939G>A p.V647I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as rs367805855, COSV54057287; called by mutect2, varscan2
- PCDHGA5 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV54048493; called by muse, mutect2, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 30/178 reads (17%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCED1B | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV71395727; called by muse, mutect2, varscan2
- PCF11 | c.1286del p.K429Rfs*7 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | catalogued as rs747292217; called by mutect2, pindel, varscan2
- PCLO | c.6244C>A p.P2082T | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV61673547; called by muse, mutect2, varscan2
- PCMTD2 | c.382_384del p.F128del | In Frame Del (DEL) | VAF 9/74 reads (12%) | catalogued as rs778338886; called by pindel, varscan2
- PCNX2 | c.5726C>T p.A1909V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99266748; called by mutect2, varscan2
- PDE4A | c.1061G>A p.R354Q (on ENST00000380702 / NM_001111307.2; = p.R115Q on NM_006202.3) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1269711202, COSV53351868; called by muse, mutect2, varscan2
- PDHX | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.156); catalogued as COSV57169882; called by muse, mutect2, varscan2
- PDK1 | c.899del p.P300Lfs*13 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | catalogued as COSV56376347; called by pindel, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs759495724; called by mutect2, varscan2
- PDZD2 | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.631); catalogued as COSV56875175; called by muse, mutect2, varscan2
- PDZD2 | c.5281A>G p.S1761G | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1189355264, COSV56875188; called by muse, mutect2, varscan2
- PELI3 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.418); catalogued as COSV57858012; called by muse, mutect2, varscan2
- PELP1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs377024175; called by muse, mutect2, varscan2
- PER2 | c.3059C>T p.A1020V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs767973991, COSV54528622; called by muse, varscan2
- PFKP | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.228); catalogued as rs775499457, COSV101127100; called by muse, mutect2, varscan2
- PGBD4 | c.1544C>T p.T515I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV56629476; called by muse, mutect2, varscan2
- PHEX | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.047); catalogued as COSV65079595; called by muse, mutect2, varscan2
- PHF12 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as rs999428680, COSV52022590; called by muse, mutect2, varscan2
- PHKA1 | c.3577C>G p.P1193A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1386922442; called by muse, mutect2
- PIDD1 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749871545, COSV57193503; called by mutect2, varscan2
- PIK3C2B | c.4256T>G p.L1419R | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.828); catalogued as COSV65814648; called by muse, mutect2, varscan2
- PIK3C2B | c.2341C>A p.L781M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65814653; called by muse, mutect2, varscan2
- PIK3CD | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.315); catalogued as rs774975013, COSV63127478; called by mutect2, varscan2
- PIK3R4 | c.2992C>T p.R998* | Nonsense Mutation (SNP) | VAF 26/144 reads (18%) | catalogued as COSV63244361; called by muse, mutect2, varscan2
- PIP4P1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.887); catalogued as COSV51659068; called by muse, mutect2
- PIWIL2 | c.1034A>G p.D345G | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV63254433; called by muse, mutect2, varscan2
- PIWIL2 | c.2657+1G>A p.X886_splice | Splice Site (SNP) | VAF 37/118 reads (31%) | catalogued as COSV63254439; called by muse, mutect2, varscan2
- PLA2G2D | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV64282126; called by muse, mutect2, varscan2
- PLA2G3 | c.42_43insT p.G15Wfs*52 | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | catalogued as COSV99311473; called by mutect2, pindel, varscan2
- PLA2R1 | c.4119del p.G1374Afs*32 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | catalogued as rs746999253; called by mutect2, varscan2
- PLAU | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234630259, COSV65640603; called by muse, mutect2, varscan2
- PLCB3 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV54188183; called by muse, mutect2, varscan2
- PLCB4 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53795682; called by muse, mutect2, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs772701630; called by mutect2, varscan2
- PMEL | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs866948103, COSV59384936; called by muse, mutect2, varscan2
- PNMA8A | c.20T>C p.M7T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV58139544; called by muse, mutect2, varscan2
- POSTN | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV65714977; called by muse, mutect2
- PPM1G | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs768747491, COSV59769050; called by muse, mutect2, varscan2
- PPP1R12B | c.2486C>T p.T829M | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs753461459, COSV51784253; called by muse, mutect2, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as rs1365223299; called by mutect2, pindel
- PPP1R36 | c.773A>G p.E258G | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.311); catalogued as COSV53904202; called by muse, mutect2, varscan2
- PPP2R2C | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58677266; called by muse, mutect2, varscan2
- PPP2R3A | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.131); catalogued as COSV53863483, COSV53871763; called by muse, mutect2
- PPP2R3B | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66812794; called by muse, mutect2, varscan2
- PPP4R3A | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.168); catalogued as rs758213999, COSV61503688; called by muse, mutect2, varscan2
- PPT2 | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV52999826; called by muse, mutect2, varscan2
- PRB1 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 65/160 reads (41%) | catalogued as rs766131639, COSV53705096; called by muse, mutect2, varscan2
- PRCP | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 20/108 reads (19%) | catalogued as rs1213516206, COSV57287271; called by muse, mutect2, varscan2
- PRDM15 | c.647del p.P216Rfs*22 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as COSV54156899; called by mutect2, pindel, varscan2
- PRDM2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as rs750635108, COSV52444829; called by muse, varscan2
- PRG4 | c.1904C>T p.T635I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV63356612; called by mutect2, varscan2
- PRKDC | c.11965C>T p.R3989W | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58047486; called by muse, mutect2, varscan2
- PRODH2 | c.1573C>T p.R525W (on ENST00000301175; = p.R449W on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs376496955; called by muse, mutect2, varscan2
- PROKR2 | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV54089718; called by muse, mutect2, varscan2
- PRPF40B | c.69del p.M24* (on ENST00000380281; = p.M18* on NM_012272.3) | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as COSV56058305; called by mutect2, pindel, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs753236928; called by mutect2, varscan2
- PRR12 | c.3162C>T p.D1054= (on ENST00000615927; = p.D1875= on NM_020719.3) | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as rs775080710, COSV69820497; called by mutect2, varscan2
- PRTN3 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV52256498; called by muse, mutect2, varscan2
- PSKH2 | c.640del p.S214Vfs*6 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | catalogued as rs773860870, COSV52613193; called by mutect2, pindel
- PSMA7 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs757469011, COSV53384005; called by mutect2, varscan2
- PSMB8 | c.572C>A p.T191N (on ENST00000374882 / NM_148919.4; = p.T187N on NM_004159.5) | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.137); catalogued as COSV62756052; called by muse, mutect2, varscan2
- PSMC2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53009348; called by muse, mutect2, varscan2
- PSMC3IP | c.170A>G p.Q57R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as COSV53819125; called by muse, mutect2, varscan2
- PTBP1 | c.1393G>A p.V465I (on ENST00000349038 / NM_031991.4; = p.V491I on NM_002819.5) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV62462059; called by muse, mutect2, varscan2
- PTCHD3 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); catalogued as rs147881350; called by mutect2, varscan2
- PTDSS2 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs371827342; called by muse, mutect2, varscan2
- PTEN | c.164+2T>C p.X55_splice | Splice Site (SNP) | VAF 17/88 reads (19%) | catalogued as rs1337554479, CS1111474, COSV64308773; called by muse, mutect2, varscan2
- PTGDR | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV60095396; called by muse, mutect2
- PTGES2 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.618); catalogued as rs751124073, COSV99476301; called by muse, mutect2, varscan2
- PTGS1 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as rs753672636, COSV56294208, COSV56295190; called by muse, mutect2, varscan2
- PTH2R | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as rs149710383; called by muse, mutect2, varscan2
- PTK2B | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs753724315, COSV57767702; called by muse, mutect2, varscan2
- PTPRJ | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV69254999; called by muse, mutect2
- PWWP2A | c.1001del p.K334Rfs*25 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | catalogued as COSV61048365; called by mutect2, pindel, varscan2
- PXDNL | c.2630C>T p.T877M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1263812907, COSV62485776; called by muse, varscan2
- PXDNL | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs936865843, COSV62476590; called by muse, varscan2
- PYGB | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769655708, COSV53817272; called by muse, mutect2, varscan2
- PYGB | c.1112_1114del p.K371del | In Frame Del (DEL) | VAF 9/87 reads (10%) | catalogued as rs1568693291; called by pindel, varscan2
- PYGL | c.2254T>C p.S752P | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV53589426; called by muse, mutect2, varscan2
- QRICH2 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.409); catalogued as rs148029652, COSV53158517; called by muse, mutect2, varscan2
- RAB3GAP2 | c.4064C>T p.A1355V | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as COSV56964870; called by muse, mutect2, varscan2
- RAD51 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV51114304; called by muse, mutect2
- RAD54L | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as rs369552170; called by muse, mutect2, varscan2
- RALGAPA1 | c.1826del p.N609Ifs*2 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | catalogued as rs748033282; called by mutect2, varscan2
- RAPGEF1 | c.2749A>G p.M917V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100940794, COSV64702727; called by muse, mutect2, varscan2
- RAPH1 | c.617A>T p.N206I | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as rs1475305900, COSV57358514; called by muse, mutect2, varscan2
- RARB | c.748A>G p.T250A (on ENST00000383772 / NM_001290216.2; = p.T243A on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV58071514; called by muse, mutect2, varscan2
- RASSF1 | c.613C>T p.R205C (on ENST00000357043 / NM_170714.2; = p.R201C on NM_007182.5) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs750917798, COSV51700421; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBM15 | c.2312A>G p.D771G | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV63924642; called by muse, mutect2, varscan2
- RBM34 | c.244dup p.T82Nfs*5 | Frame Shift Ins (INS) | VAF 18/147 reads (12%) | catalogued as rs768846936; called by mutect2, varscan2
- RBM39 | c.1304A>G p.Q435R (on ENST00000253363 / NM_001323424.2; = p.Q429R on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV53618395; called by muse, mutect2, varscan2
- RBM6 | c.2280del p.K760Nfs*101 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as rs1559645154; called by mutect2, pindel, varscan2
- RBP3 | c.3166C>T p.L1056F | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1555211792; called by muse, mutect2, varscan2
- RBPJL | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373532450, COSV100636951; called by mutect2, varscan2
- RC3H1 | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51222350; called by muse, mutect2, varscan2
- REEP4 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs757471135, COSV57942895, COSV57943090; called by mutect2, varscan2
951 further variants in this file (564 protein-altering or splice-affecting, 351 silent, 36 other) are not listed here.
